Somatic mutation profile of tumor specimen ER-ADRU-TTP1-A (aliquot ER-ADRU-TTP1-A-1-0-D-A518-34) from EXCEPTIONAL_RESPONDERS case ER-ADRU, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.7 years (24,714 days).
Specimen ER-ADRU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cb46df1-cf1f-466e-9167-b7764e97cf55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ADRU-NT1-A (Solid Tissue Normal), aliquot ER-ADRU-NT1-A-1-0-D-A518-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2922356a-2e95-4723-a872-682279ba5e10

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 2, Splice Site 2, Frame Shift Del 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD18A | c.2592A>T p.K864N | Missense Mutation (SNP) | VAF 24/709 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1447287395; called by muse, mutect2
- CGN | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs779332921; called by mutect2, varscan2
- LTBP1 | c.2218G>A p.V740I (on ENST00000404816 / NM_206943.4; = p.V414I on NM_000627.4) | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs763406365, COSV63189587; called by muse, mutect2
- OR13C5 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV66165292; called by muse, mutect2
- SLF1 | c.1017A>G p.I339M | Missense Mutation (SNP) | VAF 24/804 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54373514; called by muse, mutect2
- VSTM4 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.9); catalogued as COSV100251544; called by muse, mutect2
- ZNF43 | c.2194C>A p.Q732K | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1363317472, COSV61684579; called by muse, mutect2
- ZNF90 | c.1673G>T p.S558I | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs552166239, COSV69002846; called by muse, mutect2
- ACVR1 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DCAF6 | c.2187G>T p.W729C (on ENST00000312263 / NM_001349778.1; = p.W749C on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- FLYWCH1 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 3/56 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2
- FN1 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 23/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP2K4 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2
- RBM10 | c.992T>A p.V331E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- SUN5 | c.535-1G>A p.X179_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- TBC1D31 | c.2086A>T p.R696W | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TM7SF2 | c.492del p.N165Tfs*45 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by pindel, varscan2
- TNPO1 | c.2339-1G>A p.X780_splice | Splice Site (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- WBP2NL | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, varscan2
- ZNF292 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF846 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2
- DGKI | c.546G>A p.E182= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV55965922; called by muse, mutect2, varscan2
- ROBO1 | c.450G>A p.R150= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1675-203G>T | Intron (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- MYLK2 | c.-13G>A | 5'UTR (SNP) | VAF 6/39 reads (15%) | catalogued as rs397517470, COSV65658668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
